Somatic mutation profile of tumor specimen ALCH-B4ZQ-TTP1-A (aliquot ALCH-B4ZQ-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B4ZQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,626 days).
Specimen ALCH-B4ZQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c86a5dd4-0653-4865-8f14-f5fabe83138f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4ZQ-NB1-A (Blood Derived Normal), aliquot ALCH-B4ZQ-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/057a8d5c-1b2e-4ad2-a277-2026bef47426

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Intron 4, Nonsense Mutation 2, 5'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 86/513 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AMIGO2 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 42/283 reads (15%) | catalogued as COSV99030572; called by muse, mutect2, varscan2
- ANK2 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1276438357; called by muse, mutect2
- CHD9 | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68299304; called by muse, mutect2
- MKI67 | c.9584C>T p.S3195L | Missense Mutation (SNP) | VAF 44/428 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV64076628; called by muse, mutect2
- OR14A16 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62926205; called by muse, mutect2, varscan2
- RAPGEF6 | c.4127T>C p.F1376S | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as COSV57255793; called by muse, mutect2
- RHBDF2 | c.2252A>G p.N751S | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV51685432; called by muse, mutect2, varscan2
- ST6GAL2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | PolyPhen benign (0.003); catalogued as COSV100868311; called by mutect2, varscan2
- TNKS2 | c.1115C>G p.A372G | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV65415441, COSV65416788; called by muse, mutect2
- TVP23C | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as rs1185491166, COSV99846712; called by muse, mutect2, varscan2
- ALMS1 | c.5630G>A p.G1877E | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP10 | c.2351A>G p.K784R | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- BRD1 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- FAM71C | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FAM9A | c.422A>C p.D141A | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- FCGBP | c.2915G>C p.R972P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- HOMEZ | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.273); called by muse, mutect2
- KCNT1 | c.507C>G p.F169L (on ENST00000488444; = p.F188L on NM_020822.3) | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCOR | c.2101A>T p.S701C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- MUC5B | c.8577_8584del p.S2860Nfs*10 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- MYO18B | c.3808C>G p.R1270G | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NALCN | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NOL12 | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2
- SLC45A2 | c.1403G>A p.S468N | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- ST3GAL2 | c.28_54del p.L10_F18del | In Frame Del (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel
- STXBP4 | c.1461A>C p.K487N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TARS1 | c.703T>C p.F235L | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRIM26 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- UBE2D3 | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZBTB7A | c.1714G>T p.G572W | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- ZNF17 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- CCDC9B | c.75C>T p.F25= | Silent (SNP) | VAF 11/190 reads (6%) | called by muse, mutect2
- LCE2A | c.285C>A p.G95= | Silent (SNP) | VAF 11/89 reads (12%) | called by mutect2, varscan2
- LIMCH1 | c.2232C>A p.L744= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- MYH15 | c.2211G>C p.L737= | Silent (SNP) | VAF 11/236 reads (5%) | called by muse, mutect2
- NUDT12 | c.1386C>G p.L462= | Silent (SNP) | VAF 11/175 reads (6%) | called by muse, mutect2
- PADI6 | c.1089C>T p.F363= | Silent (SNP) | VAF 7/196 reads (4%) | called by muse, mutect2
- ABHD16A | c.626+96C>G | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- BTK | c.392-35G>T | Intron (SNP) | VAF 19/357 reads (5%) | called by muse, mutect2
- HECTD4 | c.12047-30G>T | Intron (SNP) | VAF 18/156 reads (12%) | catalogued as rs1364633369; called by muse, mutect2, varscan2
- PVRIG | c.-25G>A | 5'UTR (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- TYRP1 | c.913+43A>G | Intron (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
